Somatic mutation profile of tumor specimen 0DGOAP from CCDI case PBBTRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,153 days).
Specimen 0DGOAP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3560295f-c745-4910-bfbf-e0637d3b90ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56526357-7fb2-45bf-8322-b1975368aa68

The open-access MAF lists 425 somatic variants for this specimen: 258 protein-altering or splice-affecting, 85 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 85, Intron 53, Frame Shift Del 29, Frame Shift Ins 15, 3'UTR 13, 5'UTR 11, Nonsense Mutation 9, In Frame Del 5, 3'Flank 3, Splice Region 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 227/480 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- COL4A3 | c.713del p.P238Rfs*9 | Frame Shift Del (DEL) | VAF 52/433 reads (12%) | catalogued as rs988439345, COSV67414865; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 217/422 reads (51%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 186/461 reads (40%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 127/411 reads (31%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 377/899 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 300/778 reads (39%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC011462.1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 271/615 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1236617601; called by muse, mutect2, varscan2
- ADD1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 197/398 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs374663989; called by muse, mutect2, varscan2
- AKAP17A | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 320/516 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1410020935; called by muse, mutect2
- AMER1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 428/1044 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs767567473, COSV57656123; called by muse, mutect2, varscan2
- ANAPC1 | c.3773G>A p.G1258D | Missense Mutation (SNP) | VAF 199/535 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61974011; called by muse, mutect2, varscan2
- ANK1 | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 347/747 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375019877; called by muse, mutect2, varscan2
- ANK3 | c.7448C>T p.S2483L | Missense Mutation (SNP) | VAF 58/601 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs147863456; called by muse, mutect2
- ANKRD1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 37/590 reads (6%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs746392266, COSV65468067; ClinVar: uncertain significance; called by muse, mutect2
- ARFGEF3 | c.4894G>A p.G1632S | Missense Mutation (SNP) | VAF 167/447 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs767758942; called by muse, mutect2, varscan2
- ARID1A | c.4654C>T p.Q1552* | Nonsense Mutation (SNP) | VAF 168/437 reads (38%) | catalogued as COSV100250960; called by muse, mutect2, varscan2
- ASL | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 334/744 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs372272449, CM141287; called by muse, mutect2, varscan2
- BAHCC1 | c.6907C>T p.R2303C | Missense Mutation (SNP) | VAF 744/1228 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297551379, COSV57030110; called by muse, mutect2, varscan2
- BAZ2B | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 317/581 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs201182603; called by muse, mutect2, varscan2
- BMT2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 253/590 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51776280; called by muse, mutect2, varscan2
- C1QL1 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 683/1106 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs752313646; called by muse, mutect2, varscan2
- C9orf116 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 301/714 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs533085223, COSV54093527; called by muse, mutect2, varscan2
- CACNG3 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 358/838 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs746746638; called by muse, mutect2, varscan2
- CATSPER1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 357/816 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs756226578; called by muse, mutect2, varscan2
- CCDC130 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 494/1099 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757251716; called by muse, mutect2, varscan2
- CD1E | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 559/1230 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs560510473, COSV63769947, COSV63771242; called by muse, mutect2, varscan2
- CDC14C | c.472G>A p.E158K (on ENST00000428251; = p.E51K on NM_152627.3) | Missense Mutation (SNP) | VAF 470/1027 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as rs569396207; called by muse, mutect2, varscan2
- CEBPG | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 157/936 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs768393775; called by muse, mutect2, varscan2
- CEP250 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 440/1032 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs777053689; called by muse, mutect2, varscan2
- CFAP43 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 202/573 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1311839074; called by muse, mutect2, varscan2
- CHFR | c.1577G>A p.R526Q (on ENST00000432561 / NM_001161345.1; = p.R485Q on NM_018223.2) | Missense Mutation (SNP) | VAF 312/674 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs146156998; called by muse, mutect2, varscan2
- CIC | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 281/633 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.94); catalogued as rs1051343138; called by muse, mutect2, varscan2
- COL24A1 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 48/1046 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763486597; called by muse, mutect2
- COQ7 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 64/1208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577566239; called by muse, mutect2
- CXCR4 | c.533G>C p.S178T | Missense Mutation (SNP) | VAF 389/838 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV54012108; called by muse, mutect2, varscan2
- CYP4B1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 283/695 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs1403226616; called by muse, mutect2, varscan2
- DAPK2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 447/1009 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs144968721; called by muse, mutect2, varscan2
- DENND4B | c.22dup p.R8Pfs*20 | Frame Shift Ins (INS) | VAF 210/512 reads (41%) | catalogued as rs755611865; called by mutect2, varscan2
- DEPTOR | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 373/747 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs747175884, COSV53815630; called by muse, mutect2, varscan2
- DGCR2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 1157/1833 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1261731768; called by muse, mutect2, varscan2
- DIDO1 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 333/806 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147101685; called by muse, mutect2, varscan2
- DIPK1B | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 387/894 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs753082317; called by muse, mutect2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 344/832 reads (41%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLGAP2 | c.393dup p.R132Afs*224 | Frame Shift Ins (INS) | VAF 172/623 reads (28%) | catalogued as rs755665055; called by mutect2, pindel, varscan2
- DNMT1 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 305/1105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61579555; called by muse, mutect2, varscan2
- DSP | c.7924G>A p.V2642I | Missense Mutation (SNP) | VAF 275/729 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs869025397, COSV65795519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDC4 | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 52/521 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs986628771, COSV59304501; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 201/582 reads (35%) | catalogued as rs745309220; called by mutect2, varscan2
- ELFN1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 19/598 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1179037773; called by muse, mutect2
- EPB41L4B | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 66/1118 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.771); catalogued as rs753889477, COSV65798762; called by muse, mutect2
- ERCC2 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 383/896 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs751084702, COSV67271065; called by muse, mutect2, varscan2
- FAM47C | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 704/1493 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV100792799; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 187/445 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs200491742, COSV100436531; called by muse, mutect2, varscan2
- FUT8 | c.898C>T p.R300C (on ENST00000360689 / NM_001371534.1; = p.R137C on NM_004480.4) | Missense Mutation (SNP) | VAF 38/1074 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1461294407; called by muse, mutect2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 112/658 reads (17%) | catalogued as rs756304971; called by mutect2, varscan2
- G2E3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 183/429 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769828044, COSV52840505; called by muse, mutect2, varscan2
- GALNT13 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 206/584 reads (35%) | catalogued as rs1018857509, COSV67217164; called by muse, mutect2, varscan2
- GANAB | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 296/614 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs368589794; called by muse, mutect2, varscan2
- GJC3 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 368/858 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1038562815; called by muse, mutect2, varscan2
- GP1BB | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 235/852 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1397616627; called by muse, mutect2, varscan2
- GPC1 | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 305/943 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs751446559; called by muse, mutect2, varscan2
- GPR27 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 172/793 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.6); catalogued as rs1231092701, COSV55203646; called by muse, mutect2, varscan2
- GPR35 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 54/976 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.078); catalogued as rs758193886; called by muse, mutect2
- GRIN2A | c.3635C>T p.T1212M | Missense Mutation (SNP) | VAF 129/826 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58023346, COSV58023466; called by muse, mutect2, varscan2
- GRIN2D | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 252/657 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs1335359278; called by muse, mutect2, varscan2
- IDE | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 209/472 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs533637479; called by muse, mutect2, varscan2
- INCENP | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 474/1031 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs749966646; called by muse, mutect2, varscan2
- INSR | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 467/1051 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs79312957; called by muse, mutect2, varscan2
- IRGC | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 301/646 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs767453078, COSV99746018; called by muse, mutect2, varscan2
- KIAA0408 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 385/916 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767969756, COSV64107235; called by muse, mutect2, varscan2
- KIF26B | c.5905G>A p.V1969I | Missense Mutation (SNP) | VAF 417/877 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781292387, COSV63646165; called by muse, mutect2, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 283/710 reads (40%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel, varscan2
- KLHDC3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 44/1004 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1437335417; called by muse, mutect2
- KNDC1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 349/706 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1306483585, COSV58835700; called by muse, mutect2
- KRT13 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 190/844 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs886052908, COSV55839483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L2HGDH | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 356/808 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as rs1357308016; called by muse, mutect2, varscan2
- LAMA5 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 444/972 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751808513; called by muse, mutect2, varscan2
- LEMD2 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 84/1172 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.769); catalogued as rs752559627, COSV53393814; called by muse, mutect2
- LILRA4 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 221/507 reads (44%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.992); catalogued as rs771862808; called by muse, mutect2, varscan2
- LNX1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 275/996 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1422431248, COSV55785556; called by muse, mutect2, varscan2
- LRAT | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 342/782 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60477755; called by muse, mutect2, varscan2
- LRRIQ4 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 303/727 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.094); catalogued as rs776181036, COSV61618685; called by muse, mutect2, varscan2
- MAGEL2 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 28/936 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs1020460740, COSV58565896; called by muse, mutect2
- MAPK4 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 199/450 reads (44%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV68541356; called by muse, mutect2, varscan2
- MAT1A | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 362/786 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs114494303, COSV64747261; called by muse, mutect2, varscan2
- MATN3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 94/1121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs775138248; called by muse, mutect2
- MIB2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 54/818 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.974); catalogued as rs866781511, COSV61754967, COSV99054023; called by muse, mutect2
- MKX | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 86/1046 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs868476736, COSV101008500; called by muse, mutect2
- MTERF2 | c.-57-4dup | Splice Region (INS) | VAF 44/134 reads (33%) | catalogued as rs954774643; called by mutect2, varscan2
- MUC16 | c.19568C>T p.P6523L | Missense Mutation (SNP) | VAF 234/478 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs754683856; called by muse, mutect2, varscan2
- MUC17 | c.12344C>T p.T4115M | Missense Mutation (SNP) | VAF 453/1001 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); catalogued as rs756321309, COSV60285753; called by muse, mutect2, varscan2
- MYO1C | c.512G>A p.R171Q (on ENST00000648651 / NM_001080779.2; = p.R136Q on NM_033375.5) | Missense Mutation (SNP) | VAF 327/705 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs759605207, COSV62998379; called by muse, mutect2, varscan2
- MYO7B | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 268/700 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs367806110; called by muse, mutect2, varscan2
- NAMPT | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 294/664 reads (44%) | catalogued as COSV55995130; called by muse, mutect2, varscan2
- NCLN | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs779905685; called by muse, mutect2, varscan2
- NOTCH2 | c.5180G>A p.R1727H | Missense Mutation (SNP) | VAF 466/1046 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745954022, COSV56693160; called by muse, mutect2, varscan2
- NPC1L1 | c.3713C>T p.A1238V | Missense Mutation (SNP) | VAF 33/704 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs746780129, COSV56927192; called by muse, mutect2
- NYX | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 381/854 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV61180444; called by muse, mutect2, varscan2
- OPRD1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 412/838 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99330243; called by muse, mutect2, varscan2
- OR10C1 | c.683G>A p.R228Q (on ENST00000622521; = p.R226Q on NM_013941.3) | Missense Mutation (SNP) | VAF 25/982 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs139025176, COSV65822180; called by muse, mutect2
- OR1M1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 342/814 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs765053649, COSV70036933; called by muse, mutect2, varscan2
- OR2G2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 285/694 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1011627557, COSV60741672, COSV60742813; called by muse, mutect2, varscan2
- OR2G6 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 372/885 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs757587119, COSV58573566; called by muse, mutect2, varscan2
- OR2T27 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 323/1222 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs543746159, COSV61281246, COSV61283337; called by muse, varscan2
- OR52A1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 298/622 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs371802271; called by muse, mutect2, varscan2
- ORC4 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 143/502 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs758258444; called by muse, varscan2
- OTOGL | c.2800C>T p.R934* (on ENST00000547103; = p.R925* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/400 reads (8%) | catalogued as rs757774496, CM137545; called by muse, mutect2
- PAIP1 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 242/552 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs1379342059; called by muse, mutect2, varscan2
- PATZ1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 273/928 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs763469287, COSV56743865; called by muse, mutect2, varscan2
- PCDHB1 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 82/554 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs782348063, COSV60629465; called by muse, varscan2
- PDE8B | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 103/150 reads (69%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.586); catalogued as rs778969486, COSV99366131; called by muse, mutect2, varscan2
- PGBD1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 71/748 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1466181126; called by muse, mutect2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 268/729 reads (37%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PLCH2 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 82/1016 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs1304062233; called by muse, mutect2
- PLEC | c.12337G>A p.V4113I (on ENST00000322810 / NM_201380.4; = p.V4003I on NM_000445.5) | Missense Mutation (SNP) | VAF 331/793 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs782422260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHO2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 128/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781040665; called by muse, mutect2, varscan2
- PLS3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 24/767 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370999829, COSV56779565; called by muse, mutect2
- PNKD | c.43dup p.A15Gfs*17 | Frame Shift Ins (INS) | VAF 72/315 reads (23%) | catalogued as rs777779692; called by mutect2, pindel, varscan2
- POLRMT | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.473); catalogued as rs1425882374, COSV52112858; called by muse, mutect2, varscan2
- PPFIA1 | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 371/849 reads (44%) | catalogued as rs775192688; called by muse, mutect2, varscan2
- PRICKLE3 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 94/1103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1389845836; called by muse, mutect2
- PRSS22 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 381/873 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs111229833, COSV50720967, COSV50722066; called by muse, mutect2, varscan2
- PTBP2 | c.1387G>A p.A463T (on ENST00000426398 / NM_001300986.2; = p.A455T on NM_021190.4) | Missense Mutation (SNP) | VAF 233/619 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64623354; called by muse, mutect2, varscan2
- PTPRS | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 285/624 reads (46%) | catalogued as COSV53611032; called by muse, mutect2, varscan2
- RAF1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 67/952 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs941573221, COSV50104555; called by muse, mutect2
- RENBP | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 303/749 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs141003436; called by muse, varscan2
- RESF1 | c.4022del p.L1341Cfs*22 | Frame Shift Del (DEL) | VAF 383/997 reads (38%) | catalogued as rs35440799; called by mutect2, pindel, varscan2
- RHOXF2B | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 522/804 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs782660989, COSV65054915; called by muse, mutect2, varscan2
- RIF1 | c.3929C>T p.P1310L | Missense Mutation (SNP) | VAF 219/704 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs781064820, COSV54612624; called by muse, mutect2, varscan2
- RRBP1 | c.3484G>A p.A1162T (on ENST00000377813 / NM_001365613.2; = p.A729T on NM_004587.3) | Missense Mutation (SNP) | VAF 298/716 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs1021672375, COSV55696670; called by muse, mutect2, varscan2
- SF3B1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 374/741 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV59211147; called by muse, mutect2, varscan2
- SH3D21 | c.908G>A p.R303Q (on ENST00000453908 / NM_001162530.2; = p.R192Q on NM_024676.5) | Missense Mutation (SNP) | VAF 340/785 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs367575909; called by muse, mutect2, varscan2
- SIGLEC1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 308/740 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367731463, COSV52458176; called by muse, mutect2, varscan2
- SIRPB1 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 175/413 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as rs770208809, COSV54377543; called by muse, mutect2, varscan2
- SLC22A6 | c.777dup p.A260Cfs*11 | Frame Shift Ins (INS) | VAF 380/849 reads (45%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC51A | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 383/832 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as rs199724366, COSV56350974; called by muse, mutect2, varscan2
- SLC6A11 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 140/862 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs183457681; called by muse, mutect2, varscan2
- SLC7A10 | c.471dup p.T158Hfs*103 | Frame Shift Ins (INS) | VAF 366/852 reads (43%) | catalogued as rs753589038; called by mutect2, varscan2
- SLC7A3 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 426/1000 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs747729355, COSV104402104; called by muse, mutect2, varscan2
- SLITRK2 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 451/1072 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs782377976, COSV59423378; called by muse, mutect2
- SPATA31D3 | c.2339del p.N780Tfs*15 | Frame Shift Del (DEL) | VAF 220/670 reads (33%) | catalogued as rs772677247; called by mutect2, varscan2
- SPNS1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 198/919 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs774014230; called by muse, mutect2, varscan2
- SSRP1 | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 92/1111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53481887; called by muse, mutect2
- STXBP3 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 58/842 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750050452, COSV64181653; called by muse, mutect2
- SYNE1 | c.2734G>A p.V912I (on ENST00000367255 / NM_182961.4; = p.V919I on NM_033071.3) | Missense Mutation (SNP) | VAF 56/603 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55080530; called by muse, mutect2
- SYNE2 | c.10828G>A p.A3610T | Missense Mutation (SNP) | VAF 29/924 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs1350861349; called by muse, mutect2
- TAF1C | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 44/581 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368745604; called by muse, mutect2
- TAOK2 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 433/931 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762055796; called by muse, mutect2, varscan2
- TENM3 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 386/856 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs774602911, COSV101304641, COSV69306077; called by muse, varscan2
- TFEC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 237/586 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV55397811; called by muse, mutect2, varscan2
- TFPT | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 243/516 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV58085136; called by muse, mutect2, varscan2
- TMEM132E | c.563G>A p.R188H (on ENST00000321639; = p.R278H on NM_001304438.2) | Missense Mutation (SNP) | VAF 456/1035 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as rs761269980, COSV58696351; called by mutect2, varscan2
- TMX2 | c.391dup p.L131Pfs*6 | Frame Shift Ins (INS) | VAF 216/476 reads (45%) | catalogued as rs1274824614; called by mutect2, varscan2
- TNXB | c.7720G>A p.E2574K (on ENST00000647633; = p.E2327K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/1036 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs764604500, COSV64475307; called by muse, mutect2, varscan2
- TOPORS | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 283/725 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs745481592, COSV62116977; called by muse, mutect2, varscan2
- TRPV1 | c.1790C>T p.T597M | Missense Mutation (SNP) | VAF 454/1017 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs200059982; called by muse, mutect2, varscan2
- TSC2 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 282/668 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as rs1334081822, COSV54755399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTBK2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 231/494 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as rs368641977; called by muse, mutect2, varscan2
- TTC21A | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 40/1007 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57189367; called by muse, mutect2
- UBE2A | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 415/831 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.821); catalogued as COSV100660500, COSV60636095; called by muse, mutect2, varscan2
- UBXN11 | c.917G>A p.R306H (on ENST00000374221 / NM_183008.2; = p.R273H on NM_145345.2) | Missense Mutation (SNP) | VAF 538/1198 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs754446866, COSV54626170; called by muse, mutect2, varscan2
- UFL1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 86/1084 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1053254356, COSV65150547; called by muse, mutect2
- UGT2B11 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 75/638 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372787822; called by muse, mutect2, varscan2
- USP9X | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 191/430 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460346795, COSV61067895; called by muse, mutect2, varscan2
- WDR3 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 44/716 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754483435, COSV62523139; called by muse, mutect2
- WDR97 | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 240/734 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.089); catalogued as rs372718448; called by muse, mutect2, varscan2
- ZBED2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 65/1282 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); catalogued as rs763203398; called by muse, mutect2
- ZNF354A | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 42/546 reads (8%) | catalogued as rs1367639577; called by muse, mutect2
- ZNF407 | c.4244G>A p.R1415H | Missense Mutation (SNP) | VAF 326/906 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs767245672, COSV55243814; called by muse, mutect2, varscan2
- AARSD1 | c.24_25del p.D8Efs*21 | Frame Shift Del (DEL) | VAF 722/1454 reads (50%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 32/996 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ANK3 | c.3938A>G p.K1313R (on ENST00000280772 / NM_001320874.2; = p.K447R on NM_001149.3) | Missense Mutation (SNP) | VAF 61/884 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- AP3D1 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 82/1010 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- ATRX | c.2518del p.R840Efs*29 | Frame Shift Del (DEL) | VAF 439/1114 reads (39%) | called by mutect2, pindel, varscan2
- ATXN7L3 | c.487T>C p.S163P (on ENST00000389384 / NM_001382309.1; = p.S170P on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/629 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- BAZ2B | c.5476G>A p.A1826T | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- BECN2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 302/658 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP8B | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 366/899 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); called by muse, varscan2
- BRWD3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 34/495 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by muse, mutect2
- CA3 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 63/808 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2
- CALCR | c.1302del p.R435Gfs*29 (on ENST00000649521 / NM_001164737.2; = p.R419Gfs*29 on NM_001742.4) | Frame Shift Del (DEL) | VAF 305/816 reads (37%) | called by mutect2, pindel, varscan2
- CBLC | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 231/576 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CCDC187 | c.2465C>T p.A822V (on ENST00000638797 / NM_001378188.1; = p.A724V on NM_001291516.1) | Missense Mutation (SNP) | VAF 29/1116 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CD2AP | c.180_181del p.E60Dfs*6 | Frame Shift Del (DEL) | VAF 142/398 reads (36%) | called by pindel, varscan2
- CEP162 | c.3904A>T p.K1302* | Nonsense Mutation (SNP) | VAF 16/538 reads (3%) | called by muse, mutect2
- CFAP44 | c.1762dup p.E588Gfs*8 | Frame Shift Ins (INS) | VAF 214/596 reads (36%) | called by mutect2, pindel, varscan2
- CLCA2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2
- CMTR1 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 95/1067 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CNTNAP3B | c.545_547del p.E182del | In Frame Del (DEL) | VAF 71/339 reads (21%) | called by mutect2, pindel, varscan2
- CPEB2 | c.1080dup p.P361Afs*104 | Frame Shift Ins (INS) | VAF 219/659 reads (33%) | called by mutect2, pindel, varscan2
- CPXM1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 62/701 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- DIO3 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2
- DMGDH | c.2123A>T p.D708V | Missense Mutation (SNP) | VAF 16/537 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- DYRK1B | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 171/859 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EDRF1 | c.958G>A p.G320S (on ENST00000356792 / NM_001202438.2; = p.G286S on NM_015608.2) | Missense Mutation (SNP) | VAF 300/566 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EFL1 | c.1651del p.Q551Kfs*16 | Frame Shift Del (DEL) | VAF 72/328 reads (22%) | called by mutect2, varscan2
- EML4 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 188/584 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FHOD1 | c.2731_2733del p.E911del | In Frame Del (DEL) | VAF 307/435 reads (71%) | called by pindel, varscan2
- FHOD3 | c.4208G>A p.G1403D (on ENST00000359247 / NM_001281739.3; = p.G1420D on NM_025135.5) | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- H1-6 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 46/928 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- HDAC11 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 190/531 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIF1A | c.1640A>G p.K547R | Missense Mutation (SNP) | VAF 240/623 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- HNRNPK | c.1361G>A p.S454N | Missense Mutation (SNP) | VAF 54/716 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- IL1B | c.652A>G p.N218D | Missense Mutation (SNP) | VAF 307/806 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ITGAV | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- KASH5 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 180/412 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KIF7 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 377/889 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIRREL2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 34/477 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- KPNB1 | c.1979dup p.N660Kfs*4 | Frame Shift Ins (INS) | VAF 611/1259 reads (49%) | called by mutect2, pindel, varscan2
- LIMS1 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 115/444 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRRIQ4 | c.801C>G p.N267K | Missense Mutation (SNP) | VAF 305/752 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- LTBP2 | c.2071A>T p.I691F | Missense Mutation (SNP) | VAF 32/1122 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- MAGEL2 | c.1971dup p.A658Sfs*55 | Frame Shift Ins (INS) | VAF 209/662 reads (32%) | called by mutect2, pindel, varscan2
- MAGI2 | c.4262del p.G1421Afs*53 | Frame Shift Del (DEL) | VAF 31/333 reads (9%) | called by mutect2, pindel, varscan2
- MALRD1 | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 236/588 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.373); called by mutect2, varscan2
- NCOA7 | c.2312A>G p.E771G | Missense Mutation (SNP) | VAF 100/1118 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- NF1 | c.3991_3992del p.S1331Pfs*2 | Frame Shift Del (DEL) | VAF 233/592 reads (39%) | called by pindel, varscan2
- NXF3 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 52/1194 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.377); called by muse, mutect2
- OLIG2 | c.502_504del p.E168del | In Frame Del (DEL) | VAF 330/824 reads (40%) | called by pindel, varscan2
- PDLIM3 | c.385A>G p.K129E (on ENST00000284770 / NM_001257963.1; = p.K296E on NM_014476.6) | Missense Mutation (SNP) | VAF 42/674 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2
- PEX5L | c.139_141del p.K47del | In Frame Del (DEL) | VAF 228/570 reads (40%) | called by mutect2, pindel, varscan2
- PFKM | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 90/1101 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- PGD | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PIDD1 | c.1887G>T p.Q629H | Missense Mutation (SNP) | VAF 290/734 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PILRA | c.117del p.K39Nfs*23 | Frame Shift Del (DEL) | VAF 322/1100 reads (29%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 108/1271 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PPIE | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 298/687 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R9A | c.1424_1425del p.Y475* | Frame Shift Del (DEL) | VAF 60/638 reads (9%) | called by mutect2, pindel
- PTGS2 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 130/614 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- RAB34 | c.513+6T>C | Splice Region (SNP) | VAF 353/765 reads (46%) | called by muse, mutect2, varscan2
- RAVER1 | c.830_832del p.E277del | In Frame Del (DEL) | VAF 191/637 reads (30%) | called by pindel, varscan2
- RB1 | c.556_559del p.N186Lfs*5 | Frame Shift Del (DEL) | VAF 113/162 reads (70%) | called by mutect2, pindel, varscan2
- RBFOX3 | c.21del p.A8Pfs*38 | Frame Shift Del (DEL) | VAF 80/308 reads (26%) | called by mutect2, pindel, varscan2
- RGN | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 502/1108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RLF | c.2727_2730del p.N909Kfs*3 | Frame Shift Del (DEL) | VAF 136/848 reads (16%) | called by pindel, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 212/472 reads (45%) | called by mutect2, varscan2
- SETD1B | c.4765del p.Q1589Sfs*11 | Frame Shift Del (DEL) | VAF 82/216 reads (38%) | called by mutect2, pindel, varscan2
- SETD2 | c.3613_3616del p.Y1205Lfs*30 | Frame Shift Del (DEL) | VAF 351/843 reads (42%) | called by mutect2, pindel, varscan2
- SETD2 | c.164del p.L55Cfs*56 | Frame Shift Del (DEL) | VAF 418/1140 reads (37%) | called by mutect2, pindel, varscan2
- SH2D3A | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 58/525 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A12 | c.1120dup p.L374Pfs*232 | Frame Shift Ins (INS) | VAF 140/738 reads (19%) | called by mutect2, pindel, varscan2
- SLC41A2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 289/655 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SLC43A1 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 34/1021 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- SMC1B | c.1645del p.S549Lfs*4 | Frame Shift Del (DEL) | VAF 345/546 reads (63%) | called by mutect2, pindel, varscan2
- SNX14 | c.519dup p.A174Cfs*34 | Frame Shift Ins (INS) | VAF 222/500 reads (44%) | called by mutect2, varscan2
- TJP1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 74/586 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TMEM164 | c.757C>T p.R253C (on ENST00000372068 / NM_032227.4; = p.R104C on NM_017698.2) | Missense Mutation (SNP) | VAF 387/921 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBAP1L | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 89/831 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UGT1A3 | c.725_726dup p.V243Rfs*21 | Frame Shift Ins (INS) | VAF 384/704 reads (55%) | called by mutect2, varscan2
- VN1R4 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 238/561 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- VPS35 | c.2106del p.A703Lfs*2 | Frame Shift Del (DEL) | VAF 164/386 reads (42%) | called by mutect2, pindel, varscan2
- WDR46 | c.728+5G>A | Splice Region (SNP) | VAF 42/694 reads (6%) | called by muse, mutect2
- XIRP2 | c.3907A>G p.T1303A (on ENST00000628543; = p.T1478A on NM_152381.6) | Missense Mutation (SNP) | VAF 172/624 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZC3H4 | c.3344dup p.P1116Tfs*51 | Frame Shift Ins (INS) | VAF 189/932 reads (20%) | called by mutect2, pindel, varscan2
- ZFP42 | c.211T>G p.C71G | Missense Mutation (SNP) | VAF 53/475 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF311 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 28/702 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.172); called by muse, mutect2
- ZNF335 | c.2151del p.S718Pfs*15 | Frame Shift Del (DEL) | VAF 298/799 reads (37%) | called by mutect2, pindel, varscan2
- ABCF3 | c.909A>G p.A303= | Silent (SNP) | VAF 78/1112 reads (7%) | called by muse, mutect2
- ACTB | c.858C>T p.D286= | Silent (SNP) | VAF 233/1203 reads (19%) | catalogued as rs150105166; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTR3 | c.189T>C p.G63= | Silent (SNP) | VAF 244/533 reads (46%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2538C>T p.A846= | Silent (SNP) | VAF 63/811 reads (8%) | catalogued as rs778002659; called by muse, mutect2
- ANGPTL3 | c.894G>A p.T298= | Silent (SNP) | VAF 266/629 reads (42%) | catalogued as rs781130657, COSV52011688; called by muse, mutect2, varscan2
- APOBEC3D | c.903C>T p.A301= | Silent (SNP) | VAF 403/517 reads (78%) | catalogued as rs751024970, COSV53328005, COSV53329503; called by muse, mutect2, varscan2
- ATF7IP | c.327T>C p.C109= | Silent (SNP) | VAF 141/785 reads (18%) | called by muse, mutect2, varscan2
- ATP1B2 | c.762C>T p.N254= | Silent (SNP) | VAF 522/1002 reads (52%) | catalogued as rs775266720; called by muse, mutect2, varscan2
- BCL11B | c.2520G>A p.T840= (on ENST00000357195 / NM_001282237.2; = p.T769= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 298/678 reads (44%) | catalogued as rs1445917463, COSV61734105; called by muse, mutect2, varscan2
- BRCA1 | c.2277A>G p.Q759= | Silent (SNP) | VAF 357/1326 reads (27%) | called by muse, mutect2, varscan2
- CHD3 | c.636A>G p.A212= | Silent (SNP) | VAF 231/539 reads (43%) | catalogued as rs1169985853, COSV57873454; called by muse, mutect2, varscan2
- CLN6 | c.678C>T p.T226= | Silent (SNP) | VAF 221/539 reads (41%) | catalogued as rs374744816; called by muse, mutect2, varscan2
- COL4A3 | c.351C>T p.Y117= | Silent (SNP) | VAF 350/663 reads (53%) | catalogued as rs750308686, CM052196; called by muse, mutect2, varscan2
- CORO2A | c.1410C>T p.D470= | Silent (SNP) | VAF 261/682 reads (38%) | catalogued as rs373005604, COSV59663763; called by muse, mutect2, varscan2
- CPNE7 | c.282C>T p.Y94= | Silent (SNP) | VAF 56/379 reads (15%) | catalogued as rs781348698; called by muse, mutect2, varscan2
- DAB1 | c.939A>G p.P313= (on ENST00000371231; = p.P280= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 478/1086 reads (44%) | called by muse, mutect2, varscan2
- DCTN1 | c.3366C>A p.S1122= | Silent (SNP) | VAF 155/499 reads (31%) | called by muse, mutect2, varscan2
- DNAH10 | c.8163A>G p.S2721= (on ENST00000409039; = p.S2660= on NM_207437.3) | Silent (SNP) | VAF 195/920 reads (21%) | called by muse, mutect2, varscan2
- DNAH11 | c.2499C>T p.N833= | Silent (SNP) | VAF 146/856 reads (17%) | catalogued as rs201231307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL1 | c.1062G>A p.P354= | Silent (SNP) | VAF 330/792 reads (42%) | catalogued as rs1160297819, COSV59562139; called by muse, mutect2, varscan2
- DYRK1A | c.477C>T p.Y159= | Silent (SNP) | VAF 53/806 reads (7%) | catalogued as rs1049773; ClinVar: likely benign; called by muse, mutect2
- FAM47B | c.1113C>T p.T371= | Silent (SNP) | VAF 411/959 reads (43%) | catalogued as rs759572768, COSV61454837; called by muse, mutect2, varscan2
- FAT4 | c.7593C>T p.N2531= | Silent (SNP) | VAF 438/529 reads (83%) | catalogued as rs367971071; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRD | c.393G>A p.S131= | Silent (SNP) | VAF 527/1150 reads (46%) | catalogued as rs755920072, COSV66080426; called by muse, mutect2, varscan2
- GARRE1 | c.831C>T p.I277= | Silent (SNP) | VAF 112/669 reads (17%) | catalogued as rs770457248, COSV55103546; called by muse, mutect2, varscan2
- GDF5 | c.1482C>T p.V494= | Silent (SNP) | VAF 207/484 reads (43%) | catalogued as rs764573873, COSV65500618; called by muse, mutect2, varscan2
- GPR139 | c.363G>A p.P121= | Silent (SNP) | VAF 352/804 reads (44%) | catalogued as rs748486913; called by muse, mutect2, varscan2
- GPR68 | c.426C>T p.S142= | Silent (SNP) | VAF 203/461 reads (44%) | catalogued as rs531128570; called by muse, mutect2, varscan2
- HECTD4 | c.9696C>T p.G3232= | Silent (SNP) | VAF 52/925 reads (6%) | catalogued as rs1333967512, COSV66393462; called by muse, mutect2
- HMGCS1 | c.1269C>T p.F423= | Silent (SNP) | VAF 279/638 reads (44%) | catalogued as rs150826961; called by muse, mutect2, varscan2
- HRNR | c.5052T>A p.R1684= | Silent (SNP) | VAF 30/864 reads (3%) | called by muse, mutect2
- HS3ST3B1 | c.888C>T p.S296= | Silent (SNP) | VAF 241/939 reads (26%) | catalogued as rs766486063; called by muse, varscan2
- HS6ST1 | c.1050C>T p.Y350= | Silent (SNP) | VAF 218/537 reads (41%) | catalogued as rs541648176; called by muse, mutect2, varscan2
- HSPG2 | c.12579C>T p.S4193= | Silent (SNP) | VAF 296/714 reads (41%) | catalogued as rs773918784; called by muse, mutect2, varscan2
- INF2 | c.639G>A p.A213= | Silent (SNP) | VAF 500/1110 reads (45%) | catalogued as rs149858291; ClinVar: likely benign; called by muse, mutect2, varscan2
- ISYNA1 | c.429G>A p.S143= | Silent (SNP) | VAF 241/569 reads (42%) | catalogued as rs1006136397; called by muse, mutect2, varscan2
- ITGA7 | c.780G>A p.P260= | Silent (SNP) | VAF 235/502 reads (47%) | catalogued as rs761948061, COSV57691956; called by muse, varscan2
- ITPR1 | c.3909C>T p.H1303= (on ENST00000354582; = p.H1288= on NM_002222.7) | Silent (SNP) | VAF 278/694 reads (40%) | catalogued as rs770782177, COSV56969773; called by muse, mutect2, varscan2
- KANSL1 | c.3027G>A p.P1009= (on ENST00000574590 / NM_001193465.2; = p.P1010= on NM_015443.4) | Silent (SNP) | VAF 224/693 reads (32%) | catalogued as rs748843892; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDF1 | c.666G>A p.S222= | Silent (SNP) | VAF 418/898 reads (47%) | catalogued as rs572491048, COSV100264700, COSV57671782; called by muse, mutect2, varscan2
- KDR | c.3283C>T p.L1095= | Silent (SNP) | VAF 193/1491 reads (13%) | catalogued as rs141928074; called by muse, mutect2, varscan2
- KIF9 | c.912G>A p.S304= | Silent (SNP) | VAF 75/479 reads (16%) | catalogued as rs755773257; called by muse, mutect2, varscan2
- KLHL30 | c.1608C>T p.Y536= | Silent (SNP) | VAF 35/598 reads (6%) | catalogued as rs771381303; called by muse, mutect2
- LAMA3 | c.3288G>A p.S1096= | Silent (SNP) | VAF 349/881 reads (40%) | catalogued as rs368422951; called by muse, varscan2
- LGMN | c.645G>A p.S215= | Silent (SNP) | VAF 161/394 reads (41%) | catalogued as rs753838339, COSV58402853, COSV58404575; called by muse, mutect2, varscan2
- LRRK1 | c.5055C>T p.D1685= | Silent (SNP) | VAF 252/541 reads (47%) | catalogued as rs769765002; called by muse, mutect2, varscan2
- MAOB | c.303G>A p.G101= | Silent (SNP) | VAF 214/603 reads (35%) | catalogued as rs1192138696, COSV65205104; called by muse, mutect2, varscan2
- NCAPD3 | c.1476G>A p.T492= | Silent (SNP) | VAF 135/431 reads (31%) | catalogued as rs146072600, COSV101599330; called by muse, mutect2, varscan2
- NDN | c.252C>T p.S84= | Silent (SNP) | VAF 70/926 reads (8%) | catalogued as rs1337187322, COSV59358337; called by muse, mutect2
- NMNAT2 | c.156C>T p.H52= | Silent (SNP) | VAF 266/608 reads (44%) | catalogued as rs201834345, COSV54268902; called by muse, mutect2, varscan2
- NOM1 | c.1485C>T p.T495= | Silent (SNP) | VAF 392/890 reads (44%) | catalogued as rs143153161; called by muse, varscan2
- NOTCH3 | c.4608C>T p.S1536= | Silent (SNP) | VAF 242/548 reads (44%) | catalogued as rs1022338647; called by muse, mutect2, varscan2
- NSD1 | c.3993C>T p.D1331= | Silent (SNP) | VAF 316/371 reads (85%) | catalogued as rs539886192; called by muse, mutect2, varscan2
- NUP98 | c.5379T>C p.P1793= (on ENST00000359171 / NM_001365126.1; = p.P1776= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 74/1164 reads (6%) | called by muse, mutect2
- OR13A1 | c.336C>T p.Y112= | Silent (SNP) | VAF 428/950 reads (45%) | catalogued as rs773995966; called by muse, mutect2, varscan2
- PCF11 | c.4545G>A p.Q1515= | Silent (SNP) | VAF 209/1000 reads (21%) | catalogued as rs1390848689; called by muse, mutect2, varscan2
- PLK2 | c.288T>C p.C96= | Silent (SNP) | VAF 398/480 reads (83%) | called by muse, mutect2, varscan2
- POTEE | c.2011C>T p.L671= | Silent (SNP) | VAF 106/1768 reads (6%) | called by muse, mutect2
- RAB11FIP1 | c.687G>A p.T229= | Silent (SNP) | VAF 321/666 reads (48%) | catalogued as rs1217311034; called by muse, mutect2, varscan2
- RASAL2 | c.1791G>A p.A597= | Silent (SNP) | VAF 220/484 reads (45%) | catalogued as rs775977356, COSV100862650; called by muse, mutect2, varscan2
- RASGEF1B | c.699C>T p.F233= | Silent (SNP) | VAF 234/280 reads (84%) | catalogued as rs778019893; called by muse, mutect2, varscan2
- RNF213 | c.6930C>T p.D2310= | Silent (SNP) | VAF 778/1350 reads (58%) | catalogued as rs368942647; called by muse, mutect2, varscan2
- RYR1 | c.13389G>A p.A4463= | Silent (SNP) | VAF 399/917 reads (44%) | catalogued as rs1381095193, COSV62111832; called by muse, mutect2, varscan2
- SARDH | c.1392C>T p.Y464= | Silent (SNP) | VAF 304/690 reads (44%) | catalogued as rs781432712, COSV64099327; called by muse, varscan2
- SEC16A | c.6579C>T p.Y2193= | Silent (SNP) | VAF 456/1080 reads (42%) | catalogued as rs539760286, COSV51527022; called by muse, mutect2, varscan2
- SEMA3A | c.240C>T p.F80= | Silent (SNP) | VAF 293/655 reads (45%) | catalogued as rs775348886, COSV54879619; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHFL | c.345C>T p.C115= | Silent (SNP) | VAF 336/762 reads (44%) | catalogued as rs1461127224, COSV53461438; called by muse, varscan2
- SLC35G5 | c.60C>T p.S20= | Silent (SNP) | VAF 82/2121 reads (4%) | catalogued as rs374029388; called by muse, mutect2
- SNRK | c.1134G>A p.T378= | Silent (SNP) | VAF 511/1121 reads (46%) | catalogued as rs1036781403, COSV56068854; called by muse, mutect2, varscan2
- SRCIN1 | c.1590G>A p.S530= (on ENST00000621492; = p.S496= on NM_025248.3) | Silent (SNP) | VAF 72/914 reads (8%) | called by muse, mutect2
- SYNPR | c.54C>T p.C18= | Silent (SNP) | VAF 240/574 reads (42%) | catalogued as rs758510661; called by muse, varscan2
- TERT | c.2355G>A p.P785= | Silent (SNP) | VAF 254/574 reads (44%) | catalogued as rs545260840, COSV57223297, COSV57223758; ClinVar: likely benign; called by muse, varscan2
- TGFB1I1 | c.1179C>T p.C393= (on ENST00000394863 / NM_001042454.3; = p.C376= on NM_015927.4) | Silent (SNP) | VAF 27/859 reads (3%) | called by muse, mutect2
- THBS1 | c.2526G>A p.P842= | Silent (SNP) | VAF 300/681 reads (44%) | catalogued as rs150110244; called by muse, mutect2, varscan2
- THSD7B | c.1107G>A p.K369= | Silent (SNP) | VAF 291/744 reads (39%) | catalogued as rs977906115; called by muse, mutect2, varscan2
- TMEM259 | c.1650C>T p.D550= | Silent (SNP) | VAF 38/924 reads (4%) | catalogued as rs1456322150; called by muse, mutect2
- UNC5D | c.1233C>T p.G411= | Silent (SNP) | VAF 374/818 reads (46%) | catalogued as rs577473098, COSV54825858; called by muse, mutect2, varscan2
- USP32 | c.528T>C p.S176= | Silent (SNP) | VAF 48/1148 reads (4%) | called by muse, mutect2
- VWA5B2 | c.525C>T p.D175= | Silent (SNP) | VAF 42/949 reads (4%) | catalogued as rs749234716; called by muse, mutect2
- ZNF439 | c.1215T>C p.T405= | Silent (SNP) | VAF 185/400 reads (46%) | catalogued as rs1355601079; called by muse, mutect2, varscan2
- ZNF585B | c.750G>A p.A250= | Silent (SNP) | VAF 391/887 reads (44%) | catalogued as rs144159375; called by muse, mutect2, varscan2
- ZNF777 | c.1551G>A p.A517= | Silent (SNP) | VAF 233/561 reads (42%) | catalogued as rs1331539168; called by muse, mutect2, varscan2
- ZNF835 | c.1461C>T p.S487= | Silent (SNP) | VAF 251/551 reads (46%) | catalogued as COSV73379698; called by muse, mutect2, varscan2
- ZP1 | c.1587C>T p.C529= | Silent (SNP) | VAF 260/627 reads (41%) | catalogued as rs1236621177; called by muse, mutect2, varscan2
- ZRANB3 | c.1173C>T p.R391= | Silent (SNP) | VAF 213/652 reads (33%) | catalogued as rs776799423, COSV51517854; called by muse, mutect2, varscan2
- ACTN1 | c.2521-55C>T | Intron (SNP) | VAF 170/346 reads (49%) | catalogued as rs1262004773; called by muse, mutect2, varscan2
- ARHGEF18 | c.-123G>A | 5'UTR (SNP) | VAF 285/600 reads (48%) | catalogued as COSV60471647; called by muse, mutect2, varscan2
- ARHGEF3 | c.130-33992G>A | Intron (SNP) | VAF 64/784 reads (8%) | catalogued as rs970394183; called by muse, mutect2
- ATP5F1A | c.-30A>G | 5'UTR (SNP) | VAF 54/174 reads (31%) | catalogued as rs367797793; called by muse, mutect2, varscan2
- C12orf43 | c.*53del | 3'UTR (DEL) | VAF 139/374 reads (37%) | catalogued as rs767389025; called by mutect2, pindel, varscan2
- CAMK2N2 | c.*86dup | 3'UTR (INS) | VAF 18/104 reads (17%) | catalogued as rs893231888; called by mutect2, varscan2
- CAV3 | c.*58G>A | 3'UTR (SNP) | VAF 103/181 reads (57%) | catalogued as COSV100373138; called by muse, mutect2, varscan2
- CCNT1 | c.372+55del | Intron (DEL) | VAF 113/290 reads (39%) | catalogued as rs1170556617; called by mutect2, varscan2
- CEP350 | c.6285+51C>T | Intron (SNP) | VAF 100/228 reads (44%) | catalogued as rs189256910; called by muse, varscan2
- CIT | c.1401+69C>T | Intron (SNP) | VAF 59/171 reads (35%) | catalogued as rs1219856900; called by muse, mutect2, varscan2
- CLK1 | c.481+89del | Intron (DEL) | VAF 57/125 reads (46%) | called by mutect2, pindel, varscan2
- CNTN6 | c.761+51del | Intron (DEL) | VAF 32/233 reads (14%) | catalogued as rs769388520; called by mutect2, varscan2
- CSDC2 | chr22:41577525 C>T | 3'Flank (SNP) | VAF 87/126 reads (69%) | called by muse, mutect2, varscan2
- DIP2C | c.85+38249G>A | Intron (SNP) | VAF 450/1021 reads (44%) | catalogued as rs531429927; called by muse, mutect2, varscan2
- DNAJC7 | c.405+73G>A | Intron (SNP) | VAF 112/232 reads (48%) | catalogued as rs955234342; called by muse, varscan2
- DNASE1 | c.*6241C>T | 3'UTR (SNP) | VAF 68/197 reads (35%) | called by muse, mutect2, varscan2
- DTNBP1 | c.811+69C>T | Intron (SNP) | VAF 247/548 reads (45%) | catalogued as rs750121859; called by muse, mutect2, varscan2
- EGFL8 | c.431-9G>A | Intron (SNP) | VAF 234/722 reads (32%) | catalogued as rs761842065; called by muse, mutect2, varscan2
- EIF2B5 | c.1327-9del | Intron (DEL) | VAF 272/581 reads (47%) | catalogued as rs769938015; called by mutect2, varscan2
- EIF4E | c.399+67_399+71del | Intron (DEL) | VAF 133/173 reads (77%) | catalogued as rs777029697; called by pindel, varscan2
- ERCC6 | c.2829+21del | Intron (DEL) | VAF 176/372 reads (47%) | catalogued as rs763535359, COSV63387854; called by mutect2, varscan2
- ESPNL | c.-75C>T | 5'UTR (SNP) | VAF 23/82 reads (28%) | catalogued as rs1182970379; called by muse, mutect2, varscan2
- FAM168A | c.*6G>A | 3'UTR (SNP) | VAF 327/647 reads (51%) | called by muse, mutect2, varscan2
- FGD4 | c.600+47G>A | Intron (SNP) | VAF 101/226 reads (45%) | catalogued as rs774351838, COSV99846797; called by muse, mutect2, varscan2
- FNDC4 | c.249+49A>G | Intron (SNP) | VAF 77/282 reads (27%) | called by muse, mutect2, varscan2
- FUBP1 | c.1706-22dup | Intron (INS) | VAF 57/160 reads (36%) | called by mutect2, pindel, varscan2
- GADL1 | c.1250+35_1250+42del | Intron (DEL) | VAF 24/179 reads (13%) | catalogued as rs762110429; called by pindel, varscan2
- GALNS | c.-23del | 5'UTR (DEL) | VAF 100/172 reads (58%) | called by mutect2, pindel, varscan2
- GCNT2 | c.1018+17A>G | Intron (SNP) | VAF 32/450 reads (7%) | catalogued as rs748823298; called by muse, mutect2
- GPM6B | c.-14G>A | 5'UTR (SNP) | VAF 144/549 reads (26%) | catalogued as rs761932062; called by muse, mutect2, varscan2
- GSDMD | c.218-39G>A | Intron (SNP) | VAF 123/311 reads (40%) | catalogued as rs752652660; called by muse, mutect2, varscan2
- HBE1 | c.-267+102469C>T | Intron (SNP) | VAF 522/1126 reads (46%) | catalogued as rs773135109, COSV59673345; called by muse, mutect2, varscan2
- HELQ | c.297+53G>C | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- HNRNPA2B1 | c.511+33dup | Intron (INS) | VAF 88/368 reads (24%) | catalogued as rs752982811; called by mutect2, varscan2
- HR | c.2006-9del | Intron (DEL) | VAF 311/829 reads (38%) | catalogued as rs747701499; called by mutect2, pindel, varscan2
- IL1R2 | c.887+42C>T | Intron (SNP) | VAF 176/490 reads (36%) | catalogued as rs775181501, COSV60206705; called by muse, mutect2, varscan2
- ISCU | c.115-227del | Intron (DEL) | VAF 90/182 reads (49%) | catalogued as rs533406961; called by mutect2, varscan2
- KCNJ3 | c.-55C>T | 5'UTR (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2
- LCMT2 | chr15:43330576 A>G | 5'Flank (SNP) | VAF 18/254 reads (7%) | catalogued as rs868415356; called by muse, mutect2
- MAPK10 | c.451-20dup | Intron (INS) | VAF 207/329 reads (63%) | called by mutect2, pindel, varscan2
- MEIS1 | c.1115-74del | Intron (DEL) | VAF 32/124 reads (26%) | catalogued as rs570484439; called by mutect2, varscan2
- MT1HL1 | c.*63del | 3'UTR (DEL) | VAF 202/424 reads (48%) | catalogued as rs540124511; called by mutect2, varscan2
- MYL3 | chr3:46830408 C>T | 3'Flank (SNP) | VAF 250/680 reads (37%) | catalogued as rs756554324, COSV101451263; called by muse, mutect2, varscan2
- NAA10 | c.120+84T>G | Intron (SNP) | VAF 162/362 reads (45%) | called by muse, mutect2, varscan2
- NAP1L1 | c.103+84del | Intron (DEL) | VAF 39/156 reads (25%) | catalogued as rs769033503; called by mutect2, pindel, varscan2
- NAPEPLD | c.294+41A>G | Intron (SNP) | VAF 92/242 reads (38%) | called by muse, mutect2, varscan2
- NCKAP1 | c.2696-68del | Intron (DEL) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- NEBL | c.798+56del | Intron (DEL) | VAF 111/276 reads (40%) | catalogued as rs1021459295; called by mutect2, varscan2
- NEDD9 | c.12+21dup | Intron (INS) | VAF 136/348 reads (39%) | catalogued as rs759178609; called by mutect2, varscan2
- NKTR | c.374+46C>T | Intron (SNP) | VAF 167/413 reads (40%) | catalogued as rs756900599; called by muse, mutect2, varscan2
- NKTR | c.1017+46dup | Intron (INS) | VAF 96/284 reads (34%) | called by mutect2, pindel, varscan2
- NRIP3 | c.711-43del | Intron (DEL) | VAF 95/268 reads (35%) | catalogued as rs1566134614; called by mutect2, pindel, varscan2
- OSGEP | c.508-29C>A | Intron (SNP) | VAF 116/241 reads (48%) | called by muse, mutect2, varscan2
- OTP | c.-96_-95dup | 5'UTR (INS) | VAF 72/93 reads (77%) | catalogued as rs1379518548; called by mutect2, varscan2
- PDCD5 | c.-23T>C | 5'UTR (SNP) | VAF 87/213 reads (41%) | catalogued as rs369864929; called by muse, mutect2, varscan2
- PDLIM2 | c.541-15G>A | Intron (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- PHACTR1 | c.251-39482C>G | Intron (SNP) | VAF 150/322 reads (47%) | called by mutect2, varscan2
- PHC1 | c.*5G>A | 3'UTR (SNP) | VAF 69/328 reads (21%) | called by muse, mutect2, varscan2
- PLD3 | c.102+14G>A | Intron (SNP) | VAF 385/903 reads (43%) | catalogued as rs1051278101; called by muse, mutect2, varscan2
- PLEKHA1 | c.682-19_682-18insCT | Intron (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2*
- PLEKHG2 | c.883-37T>C | Intron (SNP) | VAF 108/296 reads (36%) | called by muse, mutect2
- PPM1J | c.928-73G>A | Intron (SNP) | VAF 39/87 reads (45%) | catalogued as rs1423393707; called by muse, mutect2, varscan2
- PPP3R2 | c.*52_*55del | 3'UTR (DEL) | VAF 74/194 reads (38%) | called by mutect2, pindel, varscan2
- REEP6 | c.348+40G>A | Intron (SNP) | VAF 192/518 reads (37%) | called by muse, mutect2, varscan2
- RWDD2B | c.*53del | 3'UTR (DEL) | VAF 117/245 reads (48%) | catalogued as rs36038895, COSV54502027; called by mutect2, varscan2
- RYR1 | c.10938-65C>T | Intron (SNP) | VAF 100/246 reads (41%) | called by muse, mutect2, varscan2
- SDF4 | c.715+29G>A | Intron (SNP) | VAF 285/680 reads (42%) | catalogued as rs201532216; called by muse, mutect2, varscan2
- SEMA6B | c.-20_-18del | 5'UTR (DEL) | VAF 240/680 reads (35%) | called by pindel, varscan2
- SHFL | c.235-30del | Intron (DEL) | VAF 96/262 reads (37%) | catalogued as rs761104658; called by pindel, varscan2
- SOS1 | c.2511-9del | Intron (DEL) | VAF 159/412 reads (39%) | catalogued as rs727503436; ClinVar: uncertain significance / benign / likely benign; called by mutect2, varscan2
- SUPT7L | c.-84G>T | 5'UTR (SNP) | VAF 124/307 reads (40%) | called by muse, mutect2, varscan2
- THBS4 | c.2314+11G>T | Intron (SNP) | VAF 232/307 reads (76%) | called by muse, mutect2, varscan2
- TIMMDC1 | c.*5G>A | 3'UTR (SNP) | VAF 181/437 reads (41%) | called by muse, mutect2, varscan2
- TRMO | c.410-16C>T | Intron (SNP) | VAF 122/690 reads (18%) | catalogued as rs753786534; called by muse, mutect2, varscan2
- TRMT13 | c.*156T>C | 3'UTR (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- TSEN34 | c.*385del | 3'UTR (DEL) | VAF 22/210 reads (10%) | catalogued as rs1156850349; ClinVar: benign; called by mutect2, pindel, varscan2
- TTN | c.10360+3502G>A | Intron (SNP) | VAF 234/698 reads (34%) | catalogued as rs544185501, COSV60104878; called by muse, mutect2, varscan2
- USP19 | chr3:49108389 del C | 3'Flank (DEL) | VAF 151/436 reads (35%) | catalogued as rs1217191878; called by mutect2, pindel, varscan2
- UTRN | c.10066-80C>T | Intron (SNP) | VAF 92/176 reads (52%) | catalogued as rs1262564621; called by muse, mutect2, varscan2
- VSIG10L | c.*2C>T | 3'UTR (SNP) | VAF 104/328 reads (32%) | catalogued as rs1408909451; called by muse, varscan2
- YWHAE | c.-99G>A | 5'UTR (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- ZSCAN10 | chr16:3092973 C>T | 5'Flank (SNP) | VAF 68/138 reads (49%) | catalogued as rs188518950; called by muse, mutect2, varscan2
